Somatic mutation profile of tumor specimen TCGA-FK-A3SG-01A (aliquot TCGA-FK-A3SG-01A-11D-A22D-08) from TCGA case TCGA-FK-A3SG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 21.1 years (7,710 days).
Specimen TCGA-FK-A3SG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4009ed5f-98f7-4a7c-ab7a-30bcdb997140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3SG-10A (Blood Derived Normal), aliquot TCGA-FK-A3SG-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d47861c-6cc1-4ea3-8bf9-17549e718357

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BDP1 | c.7711C>T p.Q2571* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV62429007; called by muse, mutect2, varscan2
- MARCHF8 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs1206485291, COSV60570757; called by muse, mutect2
- WDR11 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV54785521; called by muse, mutect2
- CD6 | c.855C>T p.V285= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV57835935; called by muse, mutect2
- RNF128 | c.276G>T p.A92= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55249162; called by muse, mutect2, varscan2
- ZNF324B | c.453G>C p.S151= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV60740583; called by muse, mutect2, varscan2
